BEATAML1.0 case 2426 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/f32238cd-dde1-4175-bbf3-ab8dd0d380af

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Acute myeloid leukemia with mutated NPM1: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 44.8 years (16,348 days); Progression or recurrence: no; ELN risk classification: Favorable.

Biospecimens (3 samples)
- Sample BA2115D: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
- Sample BA2400D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
- Sample BA2400R: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Fresh.
